Gene-level copy-number profile of tumor specimen TCGA-FS-A4FB-06A from TCGA case TCGA-FS-A4FB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 48.0 years (17,527 days).
Specimen TCGA-FS-A4FB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.d3e42748-3880-48d5-8bc6-238248bbdaff.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A4FB-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e979bfdf-cd4a-48d3-921f-5f96014b2748

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 10,377; copy number 2: 47,548; copy number 3: 224; copy number 4: 157; copy number 5: 1,383.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A4FB-06A-11D-A25P-01): tumor purity 0.94, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–4,587,469, 58 genes (within-gene range 0–1): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1, GLIS3, AL137071.1, GLIS3-AS1, AL359095.1, AL162419.1, RNU6-694P, SLC1A1.
- chr9:5,418,373–6,645,729, 24 genes (within-gene range 0–1): RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1.
- chr9:8,314,246–14,398,983, 45 genes (within-gene range 0–1): PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1.
- chr9:17,589,161–17,591,318, 1 gene: PABPC1P11.
- chr9:25,780,032–25,844,585, 1 gene (within-gene range 0–1): LINC01241.
- chr10:66,926,036–67,101,551, 2 genes (within-gene range 0–1): LRRTM3, AL139240.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,383 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–64,862,370, 279 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:73,991,392–85,449,040, 156 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:85,463,968–145,066,685, 948 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,373. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
